Somatic mutation profile of tumor specimen TCGA-TQ-A7RN-01A (aliquot TCGA-TQ-A7RN-01A-11D-A33T-08) from TCGA case TCGA-TQ-A7RN, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 32.4 years (11,823 days).
Specimen TCGA-TQ-A7RN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 494f0e56-ba43-4331-b216-e2f6c829ccda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RN-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RN-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76c3324e-2685-432b-9b7d-0fa137cb4057

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 19, Silent 6, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 65/163 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.831T>G p.C277W | Missense Mutation (SNP) | VAF 28/55 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as CM065496, COSV52676368, COSV52783531, COSV53164903; called by muse, mutect2, varscan2
- ADGRV1 | c.3959G>A p.R1320H | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs373945216; called by muse, mutect2, varscan2
- C5 | c.4144G>A p.D1382N | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as rs772720068, COSV99797883; called by muse, mutect2, varscan2
- CHD4 | c.2834T>G p.L945R (on ENST00000357008 / NM_001363606.2; = p.L958R on NM_001273.5) | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100539541, COSV58894775; called by muse, mutect2
- CNTN6 | c.1854G>C p.W618C | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100610087, COSV100612079; called by muse, mutect2
- GADL1 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV56986115; called by muse, mutect2, varscan2
- HLA-DQA1 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs368821483; called by muse, mutect2, varscan2
- MAN2B2 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.209); catalogued as rs772270531, COSV53454027, COSV53457259; called by muse, mutect2, varscan2
- MEGF10 | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768600085, COSV99174844, COSV99175917; called by muse, mutect2, varscan2
- MUC5AC | c.15338G>A p.G5113E | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.097); catalogued as COSV100611648; called by muse, mutect2, varscan2
- OR5L1 | c.515A>T p.N172I | Missense Mutation (SNP) | VAF 214/497 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100450345; called by muse, mutect2, varscan2
- POTED | c.1618C>A p.L540I | Missense Mutation (SNP) | VAF 78/205 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100203268; called by muse, mutect2, varscan2
- SLCO2A1 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.174); catalogued as COSV100189512, COSV60485376; called by muse, mutect2, varscan2
- TRAPPC13 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99199008; called by muse, mutect2, varscan2
- TTC26 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 29/350 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100571212; called by muse, mutect2
- UGT2A3 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1236119377, COSV99280304; called by muse, mutect2
- ZMAT1 | c.1601A>G p.H534R | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV100858983; called by muse, mutect2, varscan2
- ZMIZ1 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.936); catalogued as COSV57901811; called by muse, mutect2, varscan2
- COPS6 | c.486+3_486+6del p.X162_splice | Splice Site (DEL) | VAF 56/140 reads (40%) | called by mutect2, pindel, varscan2
- CACNA1G | c.3657G>A p.L1219= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV100662759; called by muse, mutect2, varscan2
- HUWE1 | c.4765C>T p.L1589= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99474933; called by muse, mutect2
- NEB | c.13449C>T p.A4483= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs572099716, COSV99429162; called by muse, mutect2, varscan2
- REST | c.1203G>A p.K401= | Silent (SNP) | VAF 15/501 reads (3%) | catalogued as COSV100471448; called by muse, mutect2
- TAS2R60 | c.297G>A p.Q99= | Silent (SNP) | VAF 90/319 reads (28%) | catalogued as rs750335021, COSV100223703; called by muse, mutect2, varscan2
- TENM3 | c.6937C>T p.L2313= | Silent (SNP) | VAF 5/100 reads (5%) | catalogued as rs1413855172, COSV101305559; called by muse, mutect2
